Somatic mutation profile of tumor specimen C3N-00733-03 (aliquot CPT0025900009) from CPTAC case C3N-00733, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.1 years (20,507 days).
Specimen C3N-00733-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2fb17e8-a8f9-4ceb-9473-bfda57cd293c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00733-31 (Blood Derived Normal), aliquot CPT0028480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3a26e09-170a-4ea3-ae41-b8434b78a437

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 7, Splice Site 2, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+1G>T p.X114_splice | Splice Site (SNP) | VAF 98/367 reads (27%) | hotspot (GDC flag); catalogued as rs730882032, CS044968, CS982396, COSV56543763, COSV56544858, COSV56545042, COSV56546938; called by muse, mutect2, varscan2
- ADAMTS12 | c.4174G>A p.V1392M | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs777630888, COSV100711434, COSV61275688; called by muse, mutect2, varscan2
- CDA | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV66751646; called by muse, mutect2, varscan2
- CRACD | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs761571893, COSV51721568, COSV51729215; called by muse, mutect2, varscan2
- HMCN1 | c.8596C>A p.L2866I | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99629176; called by muse, mutect2, varscan2
- IRX4 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99180752; called by muse, mutect2, varscan2
- LRFN4 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs773088818; called by muse, mutect2, varscan2
- PKD1 | c.9569G>A p.G3190E | Missense Mutation (SNP) | VAF 158/1029 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM158591; called by muse, mutect2, varscan2
- ZNF835 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.712); catalogued as COSV73379611; called by muse, mutect2
- ABCC2 | c.3615-6_3631del p.X1205_splice | Splice Site (DEL) | VAF 36/436 reads (8%) | called by mutect2, pindel
- BRI3BP | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf25 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCNO | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- CHP2 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CLPB | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CNOT10 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CPD | c.1595C>A p.S532* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- DNAH11 | c.13071_13075dup p.R4359Hfs*30 | Frame Shift Ins (INS) | VAF 39/151 reads (26%) | called by mutect2, pindel, varscan2
- DOCK1 | c.3244C>A p.P1082T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPP4 | c.2030A>T p.E677V | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DSPP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 141/1050 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, varscan2
- DUSP9 | c.314del p.V105Gfs*79 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | called by mutect2, pindel, varscan2
- ESRP2 | c.1296A>C p.E432D (on ENST00000565858 / NM_001365264.1; = p.E422D on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HECTD4 | c.11213_11230del p.R3738_P3743del | In Frame Del (DEL) | VAF 35/212 reads (17%) | called by mutect2, pindel, varscan2
- KMT2C | c.14279C>G p.S4760W | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KNL1 | c.5303_5316del p.Y1768Ffs*4 (on ENST00000346991 / NM_170589.5; = p.Y1742Ffs*4 on NM_144508.5) | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- LRP2 | c.2551A>G p.I851V | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- LRRFIP1 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MAP3K1 | c.1081G>C p.V361L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAPK7 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC2 | c.1835A>G p.K612R | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NCAM2 | c.1551C>G p.N517K | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFAF4 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PBRM1 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- PCDHA11 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 145/932 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RTN4RL2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SENP6 | c.53C>G p.A18G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- SLC35A2 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK3 | c.657C>A p.H219Q | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SORCS2 | c.2566A>T p.N856Y | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPDYC | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STIP1 | c.1492A>C p.I498L | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIM60 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC3 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNK3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF611 | c.1398T>G p.S466R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN5C | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AXIN2 | c.987T>C p.S329= | Silent (SNP) | VAF 14/388 reads (4%) | called by muse, mutect2
- CLUH | c.3177C>T p.P1059= (on ENST00000435359; = p.P1098= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- FERMT3 | c.294G>T p.R98= | Silent (SNP) | VAF 81/432 reads (19%) | called by muse, mutect2, varscan2
- PTCH1 | c.1257G>A p.V419= | Silent (SNP) | VAF 106/433 reads (24%) | catalogued as rs1060504535; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGPD4 | c.4086A>T p.A1362= | Silent (SNP) | VAF 74/430 reads (17%) | called by muse, mutect2, varscan2
- RMC1 | c.1216C>T p.L406= | Silent (SNP) | VAF 36/224 reads (16%) | called by muse, mutect2, varscan2
- ZNF292 | c.6504T>G p.T2168= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- CSF2RA | c.*145C>T | 3'UTR (SNP) | VAF 48/217 reads (22%) | catalogued as rs750257726, COSV100817396; called by muse, mutect2, varscan2
- GVINP1 | n.5046dup | RNA (INS) | VAF 22/209 reads (11%) | called by mutect2, pindel, varscan2
- HNF4A-AS1 | n.356+1330C>A | Intron (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- KRT17P1 | n.1073G>T | RNA (SNP) | VAF 58/1420 reads (4%) | called by muse, mutect2
